Gene-level copy-number profile of tumor specimen TCGA-H7-8501-01A from TCGA case TCGA-H7-8501, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 54.2 years (19,808 days).
Specimen TCGA-H7-8501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f2d762c5-cac2-407d-b486-7901b85e3e7c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-H7-8501-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/139bc184-11e5-4e27-8d89-80fd3f8dc389

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,525; copy number 2: 51,716; copy number 3: 4,331; copy number 4: 60; copy number 5: 123; copy number 6: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-H7-8501-01A-11D-2390-01): tumor purity 0.43, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 188 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:167,784–2,001,470, 123 genes, copy number 5 (broad region; genes not listed).
- chr12:2,440,189–4,694,317, 65 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
